Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A1DK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A1DK-01A (Primary Tumor).

[page 1 of 2]
1CB-0-3

Adenocarcinoma, endometrioid, NOS 8380/3

Site Code: endometrium C541

TSS Name/#: ---

1/12/11

fw

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral tubes and ovaries
- 2: SP: Right para-aortic lymph nodes
- 3: SP: Left para-aortic lymph nodes
- 4: SP: Right external iliac lymph nodes
- 5: SP: Right obturator lymph nodes
- 6: SP: Right common iliac lymph nodes
- 7: SP: Left external iliac lymph nodes
- 8: SP: Left obturator lymph nodes
- 9: SP: Left common iliac lymph nodes

DIAGNOSIS:

- 1) UTERUS, CERVIX, FALLOPIAN TUBES AND OVARIES: TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, NOS WITH EXTENSIVE SQUAMOUS METAPLASIA, FIGO GRADE III (> 50% SOLID GROWTH), NUCLEAR GRADE 2.
- THE TUMOR INVADERS TO <= HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 8 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 22 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- VASCULAR INVASION IS IDENTIFIED.
- THE MYOMETRIUM IS UNREMARKABLE.
- ALL ADNEXAE ARE UNREMARKABLE.
- 2) LYMPH NODES, RIGHT PARA-AORTIC; EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).
- 3) LYMPH NODES, LEFT PARA-AORTIC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 4) LYMPH NODES, RIGHT EXTERNAL ILIAC; EXCISION:
- TEN BENIGN LYMPH NODES (0/10).
- 5) LYMPH NODES, RIGHT OBTURATOR; EXCISION:

** Continued on next page **

[page 2 of 2]
TSS Name/#.

----- Page 2 of 6

- ONE BENIGN LYMPH NODE (0/1).
- 6) LYMPH NODE, RIGHT COMMON ILIAC; EXCISION:
- FIBROVASCULAR TISSUE.
- NO LYMPH NODE IDENTIFIED.
- 7) LYMPH NODES, LEFT EXTERNAL ILIAC; EXCISION:
- SEVEN BENIGN LYMPH NODES (0/7).
- 8) LYMPH NODES, LEFT OBTURATOR; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 9) LYMPH NODES, LEFT COMMON ILIAC; EXCISION:
- ADIPOSE TISSUE, NO LYMPH NODE IDENTIFIED.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file b14c9eb8-82e3-4891-b9eb-073e5821c101 (TCGA-AP-A1DK.9A3BB88B-F16F-4773-8912-CF519B847354.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).